Somatic mutation profile of tumor specimen TARGET-10-PAPCNP-09A (aliquot TARGET-10-PAPCNP-09A-01D) from TARGET case TARGET-10-PAPCNP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.6 years (3,508 days).
Specimen TARGET-10-PAPCNP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ae32ac0-29b0-4103-8209-aa8f8b9b3d2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCNP-10A (Blood Derived Normal), aliquot TARGET-10-PAPCNP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a85bdfd-5284-4f2c-ba83-ae2bf1cb9d09

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Frame Shift Ins 2, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM234A | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs200473849; called by muse, mutect2, varscan2
- HERC2 | c.11162A>G p.D3721G | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55312408; called by muse, mutect2, varscan2
- KAT6B | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1287506606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OOSP2 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.563); catalogued as rs765212768; called by muse, mutect2, varscan2
- OR2D2 | c.516C>G p.N172K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs1347899045; called by muse, mutect2, varscan2
- SYT9 | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs147763195; called by muse, mutect2, varscan2
- ERG | c.928_929dup p.A311Lfs*39 (on ENST00000398919 / NM_001243428.1; = p.A287Lfs*39 on NM_004449.4) | Frame Shift Ins (INS) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- TBL1XR1 | c.423_424insTG p.A142Wfs*8 | Frame Shift Ins (INS) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- KAT6B | c.5790G>A p.A1930= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as rs369127534; called by muse, mutect2
- PRKDC | c.5991T>C p.P1997= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as rs1276269785; called by muse, mutect2
- CCDC7 | c.1802-10473G>A | Intron (SNP) | VAF 30/50 reads (60%) | catalogued as rs189157812; called by muse, mutect2, varscan2
